Somatic mutation profile of tumor specimen C3N-06042-01 (aliquot CPT0438660006) from CPTAC case C3N-06042, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 37.2 years (13,572 days).
Specimen C3N-06042-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52133c66-5a15-477e-9b2f-1f1a4842d970.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06042-31 (Blood Derived Normal), aliquot CPT0444800004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa5ae95d-c2ec-4900-836d-d2d9c7148e66

The open-access MAF lists 294 somatic variants for this specimen: 178 protein-altering or splice-affecting, 102 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 102, Nonsense Mutation 9, Intron 9, Splice Region 2, RNA 2, Translation Start Site 2, 5'Flank 1, Frame Shift Del 1, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RMND1 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs397515421, CM128795; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4828G>A p.E1610K (on ENST00000272895 / NM_173076.3; = p.E1292K on NM_015657.3) | Missense Mutation (SNP) | VAF 51/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55955845; called by muse, mutect2, varscan2
- ACP3 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs974512425, COSV60486362; called by muse, mutect2, varscan2
- ACTL8 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 66/475 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64862672; called by muse, mutect2, varscan2
- ADAMTS6 | c.3082G>A p.G1028S | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs780680737; called by muse, mutect2, varscan2
- ADCY10 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146324030, CM153723; called by muse, mutect2, varscan2
- ANK3 | c.9181C>T p.P3061S | Missense Mutation (SNP) | VAF 70/350 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.992); catalogued as rs1299364308, COSV55044663; called by muse, mutect2, varscan2
- ARID2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 35/246 reads (14%) | catalogued as COSV104399055; called by muse, mutect2, varscan2
- ATP10B | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761267388, COSV58781261; called by muse, mutect2, varscan2
- ATPSCKMT | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 34/305 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs762541865; called by muse, mutect2, varscan2
- BIRC6 | c.6484G>A p.V2162I | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.071); catalogued as COSV101428642; called by muse, mutect2, varscan2
- C1orf174 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as rs374258021; called by muse, mutect2, varscan2
- C6 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV54714318; called by muse, mutect2
- CACNA1B | c.2888G>A p.R963Q | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.139); catalogued as rs1180947473; called by muse, mutect2, varscan2
- CAMTA1 | c.2274G>A p.M758I | Missense Mutation (SNP) | VAF 53/586 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV57919208; called by muse, mutect2
- CCDC113 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.166); catalogued as rs764014177, COSV54685737; called by muse, mutect2, varscan2
- CCL20 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1460896004, COSV62591176; called by muse, mutect2
- CD163 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV63131968, COSV63137796; called by muse, mutect2, varscan2
- CEACAM3 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 52/348 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs782008716; called by muse, mutect2, varscan2
- CHST8 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 66/466 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1296985746; called by muse, mutect2, varscan2
- CLEC2B | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 30/469 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57309417; called by muse, mutect2
- COL11A1 | c.4679G>A p.G1560D | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1465324011; called by muse, mutect2, varscan2
- CORIN | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.205); catalogued as rs866164544, COSV56688788; called by muse, mutect2, varscan2
- CORIN | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 90/295 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.188); catalogued as COSV56686567; called by muse, mutect2, varscan2
- DCDC1 | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs769231186; called by muse, mutect2
- DNAH5 | c.11242G>A p.E3748K | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); catalogued as COSV54243859; called by muse, mutect2, varscan2
- DNAH5 | c.7102C>T p.P2368S | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.457); catalogued as rs1305825224, COSV99451587; called by muse, mutect2
- DNAJB1 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1439733347; called by muse, mutect2, varscan2
- DSC3 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 49/441 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV64572109; called by muse, mutect2, varscan2
- EFHC1 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 59/435 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as rs995402027, COSV64136081; called by muse, mutect2, varscan2
- EMC7 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs1348414728, COSV56628595; called by muse, mutect2, varscan2
- ERBB4 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs267599191, COSV53505317; called by muse, mutect2, varscan2
- EYS | c.9334G>C p.E3112Q (on ENST00000370621 / NM_001292009.1; = p.E3091Q on NM_001142800.2) | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65467684; called by muse, mutect2
- FAT4 | c.6281G>A p.G2094E | Missense Mutation (SNP) | VAF 46/393 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as rs767846308; called by muse, mutect2, varscan2
- GALNT17 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 28/574 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774457548, COSV61148627; called by muse, mutect2
- GALNTL5 | c.91C>A p.H31N | Missense Mutation (SNP) | VAF 34/395 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs770179045; called by muse, mutect2
- GDF5 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 152/558 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs139413270; called by muse, mutect2, varscan2
- GIMAP2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 101/405 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs200007879; called by muse, varscan2
- GIPC2 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1333428662; called by muse, mutect2
- GOLGA6L2 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.069); catalogued as rs1327242315, COSV61479431; called by muse, mutect2, varscan2
- GOLGA8H | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749367389; called by muse, mutect2, varscan2
- GPR139 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 48/412 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1237205341, COSV58501502; called by muse, mutect2, varscan2
- HERC1 | c.2840C>T p.T947I | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750660049; called by muse, mutect2
- HMCN1 | c.13442C>T p.S4481F | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV54875329; called by muse, mutect2, varscan2
- HTR2C | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 71/259 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.114); catalogued as rs782628883, COSV52209570; called by muse, mutect2, varscan2
- KCNH4 | c.2713A>G p.M905V | Missense Mutation (SNP) | VAF 134/585 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1396982344; called by muse, mutect2, varscan2
- LRP1B | c.8743G>A p.D2915N | Missense Mutation (SNP) | VAF 27/402 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV67221402, COSV67277961; called by muse, mutect2
- MAGEE1 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 78/276 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782397816, COSV100819528, COSV63910611; called by muse, mutect2, varscan2
- MAMDC4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 75/400 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.975); catalogued as rs1450606592; called by muse, mutect2, varscan2
- MBL2 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs1209288010, COSV64759143; called by muse, mutect2, varscan2
- MYO18B | c.3691G>A p.G1231R | Missense Mutation (SNP) | VAF 65/485 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs747242229; called by muse, mutect2, varscan2
- NEXMIF | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV50037068; called by muse, mutect2, varscan2
- NUP98 | c.3430C>T p.R1144C (on ENST00000359171 / NM_001365126.1; = p.R1127C on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867822493, COSV61429434; called by muse, mutect2
- OLFM3 | c.1057G>A p.E353K (on ENST00000338858 / NM_001288821.1; = p.E333K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs868321545; called by muse, mutect2, varscan2
- OR10J3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 44/413 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV59954068; called by muse, mutect2, varscan2
- OR10X1 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100936633, COSV63766869; called by muse, mutect2, varscan2
- OR2C1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 50/464 reads (11%) | catalogued as COSV100514843; called by muse, mutect2
- OR52A5 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs761735684, COSV56616741; called by muse, mutect2
- OTX2 | c.249G>A p.Q83= (on ENST00000408990 / NM_172337.3; = p.Q91= on NM_021728.4) | Splice Region (SNP) | VAF 22/248 reads (9%) | catalogued as CM134793, CM1414824; called by muse, mutect2
- PCDHA11 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV56498067; called by muse, mutect2, varscan2
- PCF11 | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 84/395 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as rs750235002, COSV53528616; called by muse, mutect2, varscan2
- PCLO | c.7685C>T p.S2562F | Missense Mutation (SNP) | VAF 107/449 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs867538797; called by muse, mutect2, varscan2
- PCNX3 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 78/471 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs1378359324; called by muse, mutect2, varscan2
- PDLIM4 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 36/395 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1459127799, COSV53804461; called by muse, mutect2
- PENK | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 104/457 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as rs367963946; called by muse, mutect2, varscan2
- PLEKHH2 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56754320; called by muse, mutect2, varscan2
- PRKCB | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764831474, COSV57766972, COSV57792894; called by muse, mutect2, varscan2
- PRR14 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 63/485 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.297); catalogued as COSV54913448; called by muse, mutect2, varscan2
- PUM1 | c.3341C>T p.T1114I | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.309); catalogued as rs1462983076; called by muse, mutect2
- RARRES1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 73/519 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1335366665, COSV52961577; called by muse, mutect2, varscan2
- RASGRP4 | c.1553G>A p.R518K | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.192); catalogued as COSV99384969; called by muse, mutect2, varscan2
- RPH3A | c.1070C>T p.S357F (on ENST00000389385 / NM_001143854.2; = p.S353F on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/516 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as rs867320077, COSV66991507; called by muse, mutect2, varscan2
- RPS9 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 42/634 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1289126782; called by muse, mutect2
- SARDH | c.2714C>T p.S905L | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs757458797, COSV64099172, COSV64101303; called by muse, mutect2, varscan2
- SBF2 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 32/387 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as COSV56290234; called by muse, mutect2
- SLC27A6 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 38/394 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV99323518; called by muse, mutect2
- SLC6A5 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414139552; called by muse, mutect2, varscan2
- SLC8A1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 66/484 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60485196; called by muse, mutect2, varscan2
- SNAPC3 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs763542697, COSV101072763; called by muse, mutect2, varscan2
- SNTB2 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60349241; called by muse, mutect2, varscan2
- SNTG2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 47/346 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs368357440, COSV58013195; called by muse, mutect2, varscan2
- SNURF | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs751683227; called by muse, mutect2, varscan2
- SOCS2 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225826658, COSV61392330; called by muse, mutect2
- SOCS2 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61392528; called by muse, mutect2
- SPHKAP | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 51/420 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV60896220; called by muse, mutect2, varscan2
- SPON1 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 22/284 reads (8%) | catalogued as rs782051365, COSV59958756; called by muse, mutect2
- TINAG | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 92/407 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52508722, COSV99450811; called by muse, mutect2, varscan2
- TRANK1 | c.8152G>A p.A2718T | Missense Mutation (SNP) | VAF 56/451 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57141492; called by muse, mutect2, varscan2
- TSPAN32 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 38/450 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51722305; called by muse, mutect2
- TTN | c.13646C>T p.S4549F (on ENST00000591111; = p.S3622F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/339 reads (16%) | PolyPhen benign (0.215); catalogued as rs1226951123, COSV59918540; called by muse, mutect2, varscan2
- TTN | c.3655G>A p.E1219K (on ENST00000591111; = p.E1173K on NM_003319.4) | Missense Mutation (SNP) | VAF 29/310 reads (9%) | PolyPhen possibly damaging (0.831); catalogued as COSV60148522; called by muse, mutect2
- UNC5B | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 81/422 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.177); catalogued as rs202076199; called by muse, mutect2
- VWA5B1 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 22/260 reads (8%) | catalogued as rs777233754; called by muse, mutect2
- WDR35 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV55601340, COSV55604548; called by muse, mutect2, varscan2
- ZNF17 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 42/604 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs185148326; called by muse, mutect2
- ZNF226 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV56197498; called by muse, mutect2
- ZNF786 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 155/602 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs746088089; called by muse, mutect2, varscan2
- AADACL3 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 40/407 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ABRAXAS1 | c.260A>T p.K87I | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC092835.1 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ACSBG1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AHNAK2 | c.9520G>A p.E3174K | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.876); called by muse, varscan2
- ANK1 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 85/415 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- APOA5 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 77/437 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ARRDC2 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8A2 | c.1314G>A p.M438I | Missense Mutation (SNP) | VAF 40/352 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CACNA1C | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 26/509 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC97 | c.232T>C p.C78R | Missense Mutation (SNP) | VAF 24/504 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- CCDC97 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 34/516 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2
- CCR9 | c.458G>A p.R153K (on ENST00000357632 / NM_031200.3; = p.R141K on NM_006641.4) | Missense Mutation (SNP) | VAF 49/389 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKN2A | c.172_185del p.R58Afs*57 | Frame Shift Del (DEL) | VAF 62/409 reads (15%) | called by mutect2, pindel, varscan2
- CEACAM18 | c.1046T>C p.L349P | Missense Mutation (SNP) | VAF 54/369 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.887); called by muse, mutect2
- CFAP54 | c.6305G>A p.G2102E | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CHMP4C | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 96/411 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- COL16A1 | c.2999C>T p.P1000L | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- CRKL | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DGKK | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- DUOX1 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- DYNC1H1 | c.5072C>T p.S1691L | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- EIF2B1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ELP2 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 71/467 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- EPHB1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 54/394 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPPK1 | c.1897G>A p.G633R | Missense Mutation (SNP) | VAF 80/505 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- EYS | c.9367G>A p.E3123K (on ENST00000370621 / NM_001292009.1; = p.E3102K on NM_001142800.2) | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.422); called by muse, mutect2
- FAT4 | c.8704G>A p.D2902N | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FURIN | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GAB4 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- GFER | c.56dup p.A22Rfs*71 | Frame Shift Ins (INS) | VAF 83/486 reads (17%) | called by mutect2, pindel, varscan2
- GUSB | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 27/478 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- HSF1 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 77/417 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HSF1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 74/418 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- JSRP1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 55/441 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- KCNC3 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 50/353 reads (14%) | called by muse, mutect2, varscan2
- KIAA0232 | c.3721A>C p.N1241H | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.351); called by muse, mutect2
- KIF26B | c.6232G>A p.E2078K | Missense Mutation (SNP) | VAF 46/526 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- KIR3DL2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KIRREL2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 72/459 reads (16%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- LARP1 | c.2624C>T p.P875L (on ENST00000518297 / NM_033551.3; = p.P798L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/422 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRIG2 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2
- MAP3K10 | c.2363C>T p.S788L | Missense Mutation (SNP) | VAF 53/418 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAPKAPK3 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- MGAM2 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 23/375 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO18B | c.3692G>A p.G1231E | Missense Mutation (SNP) | VAF 66/490 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO1A | c.1067G>A p.W356* | Nonsense Mutation (SNP) | VAF 53/254 reads (21%) | called by muse, mutect2, varscan2
- NXF1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR8B2 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 64/399 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.112C>T p.L38F (on ENST00000259318 / NM_001136562.3; = p.L269F on NM_007203.5) | Missense Mutation (SNP) | VAF 63/311 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PCDH17 | c.1837C>A p.L613I | Missense Mutation (SNP) | VAF 29/597 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.062); called by muse, mutect2
- PCLO | c.11078C>T p.S3693F | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PCM1 | c.4222C>T p.H1408Y | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIK3R1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 61/519 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- PLPP5 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 91/497 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLPP5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 91/492 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POC1A | c.675T>G p.Y225* | Nonsense Mutation (SNP) | VAF 40/231 reads (17%) | called by muse, mutect2, varscan2
- PPIAL4A | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 73/582 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PPP1R3B | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 72/437 reads (16%) | called by muse, mutect2, varscan2
- RABGEF1 | c.203G>A p.W68* (on ENST00000439720 / NM_001287061.2; = p.W55* on NM_014504.3 and 29 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 70/265 reads (26%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RBMXL3 | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- RFPL2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); called by muse, mutect2
- RFPL2 | c.53T>A p.I18N | Missense Mutation (SNP) | VAF 47/402 reads (12%) | PolyPhen benign (0.308); called by muse, mutect2, varscan2
- SERTM1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SIN3B | c.1810C>T p.L604F | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- SORBS2 | c.802G>A p.G268S (on ENST00000284776 / NM_021069.5; = p.G361S on NM_003603.6) | Missense Mutation (SNP) | VAF 85/491 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TBC1D22A | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 68/464 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- TLR4 | c.481C>T p.L161F (on ENST00000355622 / NM_138554.5; = p.L121F on NM_003266.4) | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM156 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- TOE1 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- TRPC3 | c.216G>A p.L72= | Splice Region (SNP) | VAF 41/253 reads (16%) | called by muse, mutect2, varscan2
- TTC19 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 56/468 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTN | c.89869G>A p.E29957K (on ENST00000591111; = p.E22533K on NM_003319.4) | Missense Mutation (SNP) | VAF 22/322 reads (7%) | PolyPhen possibly damaging (0.453); called by muse, mutect2
- TTN | c.9419T>C p.L3140P (on ENST00000591111; = p.L3094P on NM_003319.4) | Missense Mutation (SNP) | VAF 31/444 reads (7%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- UGT2B4 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- UNC45A | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- VWA7 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 90/665 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ZBED9 | c.3721G>A p.E1241K | Missense Mutation (SNP) | VAF 60/449 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- ZNF469 | c.8707C>T p.P2903S (on ENST00000437464; = p.P2931S on NM_001367624.2) | Missense Mutation (SNP) | VAF 33/530 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2
- AC092835.1 | c.1107C>T p.A369= | Silent (SNP) | VAF 33/275 reads (12%) | called by muse, mutect2, varscan2
- ANK3 | c.1062C>A p.L354= | Silent (SNP) | VAF 52/291 reads (18%) | called by muse, mutect2, varscan2
- ASXL3 | c.5097C>T p.A1699= | Silent (SNP) | VAF 54/390 reads (14%) | called by muse, mutect2, varscan2
- BAZ2B | c.3612T>A p.A1204= | Silent (SNP) | VAF 54/383 reads (14%) | called by muse, mutect2, varscan2
- C10orf71 | c.3555G>A p.K1185= | Silent (SNP) | VAF 71/424 reads (17%) | called by muse, mutect2, varscan2
- C6orf15 | c.51C>T p.V17= | Silent (SNP) | VAF 137/624 reads (22%) | called by muse, mutect2, varscan2
- CACNG4 | c.696G>A p.R232= | Silent (SNP) | VAF 99/417 reads (24%) | called by muse, mutect2, varscan2
- CAD | c.3675C>T p.F1225= | Silent (SNP) | VAF 56/399 reads (14%) | catalogued as rs1045459324, COSV53024166; called by muse, mutect2, varscan2
- CEP55 | c.195C>T p.V65= | Silent (SNP) | VAF 34/213 reads (16%) | catalogued as rs770033814; called by muse, mutect2, varscan2
- CHRNA4 | c.408C>T p.T136= | Silent (SNP) | VAF 84/321 reads (26%) | called by muse, mutect2, varscan2
- CLCA1 | c.393G>A p.R131= | Silent (SNP) | VAF 46/346 reads (13%) | called by muse, mutect2, varscan2
- CRKL | c.660C>T p.S220= | Silent (SNP) | VAF 46/352 reads (13%) | catalogued as rs763765173, COSV100574184; called by muse, mutect2, varscan2
- CUL9 | c.1854C>T p.A618= | Silent (SNP) | VAF 64/546 reads (12%) | catalogued as COSV52734909; called by muse, mutect2, varscan2
- CYP3A7 | c.486G>A p.R162= | Silent (SNP) | VAF 17/329 reads (5%) | catalogued as COSV60481415; called by muse, mutect2
- CYP4B1 | c.1191G>A p.R397= | Silent (SNP) | VAF 50/285 reads (18%) | called by muse, mutect2, varscan2
- DENND4B | c.39C>T p.F13= | Silent (SNP) | VAF 46/355 reads (13%) | catalogued as rs746475540, COSV100339005; called by muse, mutect2, varscan2
- DISP3 | c.3879C>T p.I1293= | Silent (SNP) | VAF 50/525 reads (10%) | catalogued as rs769307396; called by muse, mutect2
- DNAH1 | c.5157C>T p.L1719= | Silent (SNP) | VAF 46/350 reads (13%) | catalogued as rs770135382, COSV101325604; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNALI1 | c.639G>A p.R213= (on ENST00000296218; = p.R191= on NM_003462.5) | Silent (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- EFNA5 | c.606G>A p.E202= | Silent (SNP) | VAF 42/390 reads (11%) | called by muse, mutect2, varscan2
- ELANE | c.192C>T p.F64= | Silent (SNP) | VAF 26/455 reads (6%) | catalogued as rs1269264963; called by muse, mutect2
- EML6 | c.1350C>T p.S450= | Silent (SNP) | VAF 53/358 reads (15%) | called by muse, mutect2, varscan2
- EP400 | c.2277C>T p.S759= | Silent (SNP) | VAF 52/393 reads (13%) | catalogued as rs1365713655; called by muse, mutect2, varscan2
- EPPK1 | c.1896G>A p.K632= | Silent (SNP) | VAF 79/511 reads (15%) | called by muse, mutect2, varscan2
- FBXO24 | c.1137C>T p.F379= (on ENST00000241071 / NM_033506.3; = p.F417= on NM_012172.5) | Silent (SNP) | VAF 84/386 reads (22%) | catalogued as rs1411019002, COSV53827517; called by muse, mutect2, varscan2
- FLT1 | c.1410C>T p.P470= | Silent (SNP) | VAF 35/402 reads (9%) | called by muse, mutect2
- GABRB2 | c.1512C>T p.I504= (on ENST00000274547; = p.I466= on NM_000813.3) | Silent (SNP) | VAF 29/313 reads (9%) | catalogued as rs761305470, COSV50903532; called by muse, mutect2, varscan2
- GALNT16 | c.519C>A p.L173= | Silent (SNP) | VAF 51/312 reads (16%) | called by muse, mutect2, varscan2
- GAPVD1 | c.511T>C p.L171= | Silent (SNP) | VAF 62/337 reads (18%) | catalogued as rs1176860087; called by muse, mutect2, varscan2
- HMCN1 | c.13306C>T p.L4436= | Silent (SNP) | VAF 28/283 reads (10%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.210C>T p.A70= | Silent (SNP) | VAF 28/370 reads (8%) | catalogued as rs1397871283, COSV100270507; called by muse, mutect2
- HNRNPR | c.666C>T p.A222= | Silent (SNP) | VAF 24/212 reads (11%) | catalogued as rs1406365797; called by muse, varscan2
- IGBP1P2 | c.1005C>T p.N335= | Silent (SNP) | VAF 51/286 reads (18%) | called by muse, mutect2, varscan2
- IL7 | c.393A>G p.E131= | Silent (SNP) | VAF 54/323 reads (17%) | called by muse, mutect2, varscan2
- IPO9 | c.3114C>T p.T1038= | Silent (SNP) | VAF 45/308 reads (15%) | called by muse, mutect2, varscan2
- IQSEC3 | c.1239C>T p.I413= (on ENST00000538872 / NM_001170738.2; = p.I110= on NM_015232.1) | Silent (SNP) | VAF 18/504 reads (4%) | catalogued as rs74875672; called by muse, mutect2
- ITGAM | c.1773C>T p.G591= (on ENST00000648685 / NM_001145808.2; = p.G590= on NM_000632.4) | Silent (SNP) | VAF 42/260 reads (16%) | catalogued as rs549300106; called by muse, varscan2
- JMJD6 | c.762C>T p.P254= | Silent (SNP) | VAF 42/430 reads (10%) | called by muse, mutect2
- KCTD13 | c.915C>T p.V305= | Silent (SNP) | VAF 45/478 reads (9%) | called by muse, mutect2
- KHDRBS3 | c.693C>T p.T231= | Silent (SNP) | VAF 93/466 reads (20%) | called by muse, mutect2, varscan2
- KIF21B | c.777G>A p.S259= | Silent (SNP) | VAF 40/296 reads (14%) | catalogued as rs749553311, COSV100144923; called by muse, mutect2, varscan2
- KRI1 | c.519C>T p.D173= | Silent (SNP) | VAF 69/436 reads (16%) | catalogued as rs374028807; called by muse, mutect2, varscan2
- KRT35 | c.564G>A p.T188= | Silent (SNP) | VAF 50/287 reads (17%) | catalogued as rs551988601, COSV99877942; called by muse, mutect2, varscan2
- KRT37 | c.609G>A p.V203= | Silent (SNP) | VAF 141/539 reads (26%) | catalogued as rs1159400284; called by muse, mutect2, varscan2
- KRT83 | c.15C>T p.F5= | Silent (SNP) | VAF 33/316 reads (10%) | called by muse, mutect2, varscan2
- LAMB4 | c.921G>A p.E307= | Silent (SNP) | VAF 37/487 reads (8%) | catalogued as rs778916207; called by muse, mutect2
- LDHAL6B | c.363G>A p.T121= | Silent (SNP) | VAF 28/256 reads (11%) | catalogued as rs536602124, COSV55697454; called by muse, mutect2, varscan2
- LPA | c.5208T>A p.V1736= | Silent (SNP) | VAF 39/408 reads (10%) | called by muse, mutect2, varscan2
- LRP1 | c.8550C>T p.S2850= | Silent (SNP) | VAF 30/288 reads (10%) | called by muse, mutect2
- MCCD1 | c.180G>A p.G60= | Silent (SNP) | VAF 57/537 reads (11%) | catalogued as rs1376572431; called by muse, mutect2, varscan2
- MIP | c.640C>T p.L214= | Silent (SNP) | VAF 49/326 reads (15%) | called by muse, mutect2, varscan2
- MST1R | c.2244C>T p.P748= | Silent (SNP) | VAF 75/484 reads (15%) | catalogued as rs1424927277; called by muse, mutect2, varscan2
- MYH2 | c.5391G>A p.K1797= | Silent (SNP) | VAF 92/484 reads (19%) | catalogued as COSV55449333; called by muse, mutect2, varscan2
- MYH4 | c.1032C>T p.F344= | Silent (SNP) | VAF 50/273 reads (18%) | catalogued as COSV99700395, COSV99700414; called by muse, mutect2, varscan2
- MYLK3 | c.354G>A p.V118= | Silent (SNP) | VAF 50/594 reads (8%) | called by muse, mutect2
- NBEA | c.5715C>T p.D1905= | Silent (SNP) | VAF 47/283 reads (17%) | called by muse, mutect2, varscan2
- NCAPD2 | c.3720C>T p.L1240= | Silent (SNP) | VAF 28/378 reads (7%) | catalogued as COSV57520997; called by muse, mutect2
- NEXMIF | c.2700C>T p.F900= | Silent (SNP) | VAF 86/284 reads (30%) | catalogued as COSV50021650, COSV99280372; called by muse, mutect2, varscan2
- NLGN1 | c.1881T>C p.T627= | Silent (SNP) | VAF 59/413 reads (14%) | called by muse, mutect2, varscan2
- ODF4 | c.742C>T p.L248= | Silent (SNP) | VAF 20/316 reads (6%) | called by muse, mutect2
- OR4A16 | c.690G>A p.E230= | Silent (SNP) | VAF 32/459 reads (7%) | catalogued as COSV100125196; called by muse, mutect2
- OR4C15 | c.99C>T p.F33= | Silent (SNP) | VAF 68/354 reads (19%) | catalogued as rs760696526, COSV58951213, COSV58956039; called by muse, mutect2, varscan2
- PAFAH2 | c.498C>T p.I166= | Silent (SNP) | VAF 61/391 reads (16%) | catalogued as COSV65339918; called by muse, mutect2, varscan2
- PCNX2 | c.3963C>T p.F1321= | Silent (SNP) | VAF 32/228 reads (14%) | catalogued as rs267598415; called by muse, mutect2, varscan2
- PCSK5 | c.819C>A p.G273= | Silent (SNP) | VAF 33/445 reads (7%) | called by muse, mutect2
- PEAK1 | c.3951C>T p.L1317= | Silent (SNP) | VAF 30/432 reads (7%) | catalogued as COSV56942879; called by muse, mutect2
- PLXNA2 | c.2869C>T p.L957= | Silent (SNP) | VAF 13/304 reads (4%) | called by muse, mutect2
- POTEJ | c.2082C>T p.F694= | Silent (SNP) | VAF 80/684 reads (12%) | catalogued as rs768395009; called by muse, varscan2
- POU6F1 | c.1105C>T p.L369= | Silent (SNP) | VAF 28/412 reads (7%) | catalogued as rs1215556587; called by muse, mutect2
- PRKCZ | c.228G>A p.L76= | Silent (SNP) | VAF 21/390 reads (5%) | called by muse, mutect2
- PXDNL | c.393C>T p.F131= | Silent (SNP) | VAF 53/311 reads (17%) | catalogued as COSV100680321; called by muse, mutect2, varscan2
- RANBP9 | c.1395C>T p.G465= | Silent (SNP) | VAF 72/346 reads (21%) | called by muse, mutect2, varscan2
- RFX6 | c.1347C>T p.F449= | Silent (SNP) | VAF 39/235 reads (17%) | catalogued as rs751839843, COSV100263115; called by muse, mutect2, varscan2
- RMND1 | c.1251G>T p.R417= | Silent (SNP) | VAF 40/284 reads (14%) | called by muse, mutect2, varscan2
- S100A9 | c.60C>T p.H20= | Silent (SNP) | VAF 41/362 reads (11%) | called by muse, mutect2, varscan2
- SAMD7 | c.378C>T p.F126= | Silent (SNP) | VAF 30/259 reads (12%) | catalogued as COSV59418858; called by muse, mutect2, varscan2
- SCN2A | c.3486G>A p.E1162= | Silent (SNP) | VAF 31/226 reads (14%) | catalogued as rs1427680081; called by muse, mutect2, varscan2
- SCN5A | c.3685C>T p.L1229= (on ENST00000333535 / NM_198056.3; = p.L1228= on NM_000335.5) | Silent (SNP) | VAF 27/227 reads (12%) | called by muse, mutect2, varscan2
- SEMA6C | c.1846C>T p.L616= | Silent (SNP) | VAF 67/476 reads (14%) | catalogued as rs587771170, COSV59000467; called by muse, mutect2, varscan2
- SERPINB11 | c.435G>A p.T145= | Silent (SNP) | VAF 30/287 reads (10%) | catalogued as rs367579501; called by muse, mutect2, varscan2
- SIPA1 | c.1458C>T p.F486= | Silent (SNP) | VAF 63/519 reads (12%) | catalogued as rs780602430; called by muse, mutect2, varscan2
- SLC7A13 | c.582G>A p.Q194= | Silent (SNP) | VAF 70/433 reads (16%) | called by muse, mutect2, varscan2
- SLIT3 | c.1932C>T p.I644= | Silent (SNP) | VAF 50/374 reads (13%) | catalogued as rs766902850, COSV100266858; called by muse, varscan2
- SYT16 | c.492T>C p.G164= | Silent (SNP) | VAF 24/306 reads (8%) | catalogued as rs1351122659; called by muse, mutect2
- TBXT | c.840A>T p.P280= | Silent (SNP) | VAF 65/384 reads (17%) | called by muse, mutect2, varscan2
- TMEM176B | c.808C>T p.L270= | Silent (SNP) | VAF 76/280 reads (27%) | catalogued as COSV58440709; called by muse, mutect2, varscan2
- TOX | c.756G>A p.K252= | Silent (SNP) | VAF 100/491 reads (20%) | called by muse, mutect2, varscan2
- TRHDE | c.1638C>T p.F546= | Silent (SNP) | VAF 32/230 reads (14%) | catalogued as COSV53833098, COSV53847881; called by muse, varscan2
- TTC19 | c.48C>T p.A16= | Silent (SNP) | VAF 57/473 reads (12%) | called by muse, mutect2, varscan2
- TUBB | c.774C>T p.V258= | Silent (SNP) | VAF 94/727 reads (13%) | called by muse, mutect2, varscan2
- TUBG1 | c.1278G>A p.E426= | Silent (SNP) | VAF 72/383 reads (19%) | called by muse, mutect2, varscan2
- UGT2A1 | c.1191G>A p.Q397= | Silent (SNP) | VAF 50/387 reads (13%) | catalogued as rs1304344649, COSV54142798; called by muse, mutect2, varscan2
- UMODL1 | c.3156G>A p.T1052= (on ENST00000408910 / NM_001004416.2; = p.T1180= on NM_173568.3) | Silent (SNP) | VAF 55/241 reads (23%) | catalogued as rs764812388, COSV68571195; called by muse, mutect2, varscan2
- UPK3BL2 | c.495C>T p.F165= | Silent (SNP) | VAF 63/472 reads (13%) | called by muse, mutect2, varscan2
- VAMP7 | c.585C>T p.I195= | Silent (SNP) | VAF 26/300 reads (9%) | catalogued as rs138653672, COSV52902817; called by muse, mutect2
- VIT | c.1740C>T p.F580= (on ENST00000389975 / NM_001177969.1; = p.F595= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/506 reads (14%) | catalogued as rs764630861, COSV64896889; called by muse, mutect2, varscan2
- VPS16 | c.1254C>T p.F418= | Silent (SNP) | VAF 57/301 reads (19%) | catalogued as rs368671330; called by muse, mutect2, varscan2
- XIRP2 | c.33C>T p.L11= | Silent (SNP) | VAF 37/247 reads (15%) | catalogued as rs767276487; called by muse, mutect2, varscan2
- XKR4 | c.969C>T p.C323= | Silent (SNP) | VAF 49/542 reads (9%) | called by muse, mutect2
- ZNF155 | c.1347C>T p.V449= | Silent (SNP) | VAF 28/404 reads (7%) | called by muse, mutect2
- ZNF581 | c.432C>T p.P144= | Silent (SNP) | VAF 44/580 reads (8%) | called by muse, mutect2
- ZNF676 | c.1470C>T p.F490= (on ENST00000650058; = p.F458= on NM_001001411.3) | Silent (SNP) | VAF 40/496 reads (8%) | called by muse, mutect2
- BCAP31 | c.-44-253C>T | Intron (SNP) | VAF 63/262 reads (24%) | called by muse, mutect2, varscan2
- CTC1 | chr17:8222893 G>C | 3'Flank (SNP) | VAF 42/303 reads (14%) | catalogued as rs190428039; called by muse, mutect2, varscan2
- CTCFL | c.1674+981C>T | Intron (SNP) | VAF 35/512 reads (7%) | called by muse, mutect2
- DCHS2 | n.47G>A | RNA (SNP) | VAF 43/326 reads (13%) | called by muse, mutect2, varscan2
- DEPDC5 | c.*975C>T | 3'UTR (SNP) | VAF 60/528 reads (11%) | catalogued as rs778708641, COSV99835344; called by muse, mutect2, varscan2
- MYL1 | c.133-1027G>A | Intron (SNP) | VAF 27/276 reads (10%) | catalogued as rs771902691, COSV58975928; called by muse, mutect2, varscan2
- RASGRP2 | c.371+11G>A | Intron (SNP) | VAF 90/395 reads (23%) | catalogued as rs771449798; called by muse, mutect2, varscan2
- SEPTIN9 | c.722-6338C>T | Intron (SNP) | VAF 127/589 reads (22%) | catalogued as rs919565361; called by muse, mutect2, varscan2
- SPATA8 | n.847G>A | RNA (SNP) | VAF 54/332 reads (16%) | catalogued as COSV60705130; called by muse, mutect2, varscan2
- ST3GAL3 | c.1083+665G>A | Intron (SNP) | VAF 48/327 reads (15%) | catalogued as rs1398173443; called by mutect2, varscan2
- ST3GAL3 | c.1083+666G>A | Intron (SNP) | VAF 48/324 reads (15%) | called by mutect2, varscan2
- TLX3 | chr5:171308454 C>T | 5'Flank (SNP) | VAF 64/472 reads (14%) | called by muse, mutect2, varscan2
- UNC5D | c.104-4782G>A | Intron (SNP) | VAF 38/332 reads (11%) | catalogued as COSV99779228; called by muse, mutect2, varscan2
- ZIC4 | c.-15-1242C>A | Intron (SNP) | VAF 51/341 reads (15%) | catalogued as COSV67173989; called by muse, mutect2, varscan2
